Somatic mutation profile of tumor specimen TCGA-VS-A9UO-01A (aliquot TCGA-VS-A9UO-01A-11D-A42O-09) from TCGA case TCGA-VS-A9UO, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 43.3 years (15,813 days).
Specimen TCGA-VS-A9UO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5e62d164-0b44-471e-bd52-8be1aff088dd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9UO-10A (Blood Derived Normal), aliquot TCGA-VS-A9UO-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e30b8531-76e7-402c-a1fd-8ee833a189e6

The open-access MAF lists 56 somatic variants for this specimen: 43 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 34, Silent 13, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 28/55 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARHGAP12 | c.2425G>C p.G809R | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100260947; called by muse, mutect2
- ARHGEF1 | c.1819C>A p.R607S | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100529232; called by muse, mutect2, varscan2
- ARMS2 | c.58G>C p.E20Q | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1377596562, COSV101600756; called by muse, mutect2, varscan2
- CCER1 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100727021; called by muse, mutect2, varscan2
- CDKAL1 | c.1055+1G>T p.X352_splice | Splice Site (SNP) | VAF 25/100 reads (25%) | catalogued as COSV99216578; called by muse, mutect2, varscan2
- CELSR1 | c.6902C>T p.P2301L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs538530181, COSV53085254; called by muse, mutect2, varscan2
- CLTB | c.384G>C p.W128C | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100125162; called by muse, mutect2, varscan2
- CUBN | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs776471095, COSV100910688; called by muse, mutect2, varscan2
- CYLD | c.665C>A p.T222K | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.87); PolyPhen benign (0.01); catalogued as rs587778225, COSV100282786; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- DNM2 | c.766A>G p.R256G | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV100118128; called by muse, mutect2, varscan2
- DNM2 | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.897); catalogued as COSV100118131; called by muse, mutect2, varscan2
- ECT2 | c.598C>T p.H200Y (on ENST00000392692 / NM_001349098.2; = p.H169Y on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/95 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV99221954; called by muse, mutect2, varscan2
- ELAPOR1 | c.2174A>C p.E725A | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100884490; called by muse, mutect2, varscan2
- EVC2 | c.683C>A p.A228D | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.416); catalogued as COSV60392668; called by muse, mutect2, varscan2
- EVI5L | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.515); catalogued as rs746339487, COSV54483945, COSV99563589; called by muse, mutect2, varscan2
- GAD1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100713946; called by muse, mutect2, varscan2
- HERC1 | c.13756A>T p.M4586L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.833); catalogued as COSV101496981; called by muse, mutect2, varscan2
- ITGAM | c.3259G>T p.G1087W (on ENST00000648685 / NM_001145808.2; = p.G1086W on NM_000632.4) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV99793212; called by muse, mutect2, varscan2
- KCNN2 | c.390G>T p.K130N (on ENST00000264773; = p.K342N on NM_021614.4) | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99300839; called by muse, mutect2, varscan2
- KCNU1 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs543181237, COSV101299446; called by muse, mutect2, varscan2
- KIDINS220 | c.3704C>A p.T1235N | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs780524866, COSV56750533, COSV99876549; called by muse, mutect2, varscan2
- KRT84 | c.127G>T p.G43* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as COSV57773906; called by muse, mutect2, varscan2
- LENG8 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs147412771; called by muse, mutect2, varscan2
- LIF | c.228C>A p.N76K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.255); catalogued as COSV99970000; called by muse, varscan2
- LRP1B | c.7166G>A p.R2389K | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs761131522, COSV101261619; called by muse, mutect2, varscan2
- NAV2 | c.1936G>C p.G646R (on ENST00000396087 / NM_001244963.2; = p.G623R on NM_145117.5) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.826); catalogued as COSV100587169; called by muse, mutect2, varscan2
- NMU | c.489+2T>A p.X163_splice | Splice Site (SNP) | VAF 11/20 reads (55%) | catalogued as COSV99946886; called by muse, mutect2, varscan2
- OR6N1 | c.403C>T p.L135F | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV100625282, COSV100625307; called by muse, mutect2, varscan2
- OSBP | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99803447; called by muse, mutect2, varscan2
- PAPOLB | c.1312T>C p.W438R | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101271630; called by muse, mutect2, varscan2
- QSOX2 | c.1024C>T p.H342Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1166290992, COSV62395143; called by muse, mutect2, varscan2
- SLC7A5 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.603); catalogued as rs547150259, COSV55364014; called by muse, mutect2, varscan2
- TAS2R10 | c.743C>A p.S248* | Nonsense Mutation (SNP) | VAF 14/38 reads (37%) | catalogued as COSV53700741, COSV99555653; called by muse, mutect2, varscan2
- TBK1 | c.177G>C p.L59F | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100538437, COSV59155109; called by muse, mutect2, varscan2
- TEP1 | c.4559-2A>T p.X1520_splice | Splice Site (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99403341; called by muse, mutect2, varscan2
- TKTL2 | c.1796G>A p.R599H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs541496760, COSV99761791; called by muse, mutect2, varscan2
- TNIK | c.3447T>A p.V1149= | Splice Region (SNP) | VAF 32/68 reads (47%) | catalogued as COSV99459829; called by muse, varscan2
- TOR1A | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV99400337; called by muse, mutect2, varscan2
- TUBGCP6 | c.5272C>T p.P1758S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as rs761960582, COSV99956440; called by muse, mutect2, varscan2
- WBP2NL | c.662C>G p.P221R | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV100173939; called by muse, mutect2, varscan2
- DEPDC5 | c.1244_1248del p.F415* | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- GLIS1 | c.1621_1636del p.D541Rfs*104 | Frame Shift Del (DEL) | VAF 28/105 reads (27%) | called by mutect2, pindel, varscan2
- BIRC6 | c.756G>A p.A252= | Silent (SNP) | VAF 61/72 reads (85%) | catalogued as rs750051821, COSV101429028; called by muse, mutect2, varscan2
- CACNA1I | c.2601G>A p.A867= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs749531032, COSV100361662; called by muse, mutect2, varscan2
- CLTB | c.294G>A p.Q98= | Silent (SNP) | VAF 7/31 reads (23%) | catalogued as COSV100125163; called by muse, mutect2, varscan2
- COL23A1 | c.597C>T p.G199= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs202101672, COSV101179829; called by muse, mutect2, varscan2
- DCAF4L2 | c.1182C>T p.Y394= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs375340661; called by muse, mutect2, varscan2
- DIDO1 | c.39T>A p.P13= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99827289; called by muse, mutect2
- DMRT1 | c.972C>T p.F324= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs1464491964, COSV101206720; called by muse, mutect2, varscan2
- KRT4 | c.1374G>A p.V458= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV99543240; called by muse, mutect2, varscan2
- OR14K1 | c.891C>T p.S297= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as rs753325788, COSV51721218; called by muse, mutect2, varscan2
- OR2G6 | c.597C>A p.L199= | Silent (SNP) | VAF 23/69 reads (33%) | catalogued as COSV100598337, COSV58573901; called by muse, mutect2, varscan2
- OR6N1 | c.402C>G p.T134= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100625308, COSV58649153; called by muse, mutect2, varscan2
- PXDN | c.657G>C p.A219= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV53232236, COSV99415113; called by muse, mutect2, varscan2
- SPCS2 | c.336C>T p.P112= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as rs775180717, COSV99734564; called by muse, mutect2, varscan2
